Somatic mutation profile of tumor specimen TCGA-CG-5717-01A (aliquot TCGA-CG-5717-01A-11D-1600-08) from TCGA case TCGA-CG-5717, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.7 years (21,458 days).
Specimen TCGA-CG-5717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cca437ea-b71c-4365-b59b-e9e36c9a7e9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5717-10A (Blood Derived Normal), aliquot TCGA-CG-5717-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3cee131-c129-4414-92fc-798b17a663b8

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Nonsense Mutation 3, Nonstop Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.496A>T p.T166S | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV56454047; called by muse, mutect2
- ADGRF1 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV64799475; called by muse, mutect2
- ASH1L | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV64205398; called by muse, mutect2
- AVL9 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV59463911; called by muse, mutect2
- BTAF1 | c.5032G>A p.D1678N | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56429813; called by muse, mutect2
- CA8 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768738585, COSV58770369; called by muse, mutect2, varscan2
- CCDC125 | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 28/411 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV67287608; called by muse, mutect2
- CGRRF1 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53595510; called by muse, mutect2
- CLCA4 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.309); catalogued as COSV55366012, COSV99760418; called by muse, mutect2
- CRISPLD1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs541154941, COSV51544170; called by muse, mutect2, varscan2
- CRX | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV55756976; called by muse, mutect2
- EBI3 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV55689500; called by muse, mutect2
- EHF | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.448); catalogued as COSV57667478; called by muse, mutect2
- F5 | c.2882A>C p.D961A | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV63120384; called by muse, mutect2
- FAT1 | c.7369C>A p.L2457M | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); catalogued as COSV71671893; called by muse, mutect2
- FBXO34 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as COSV58253303; called by muse, mutect2
- GABRA5 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as COSV59475690; called by muse, mutect2
- GPR139 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.791); catalogued as rs144836581; called by muse, mutect2, varscan2
- GPR149 | c.652T>C p.C218R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs897150384, COSV67665738; called by muse, mutect2
- ISM2 | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV53633832; called by muse, mutect2
- ITGA1 | c.1641G>C p.Q547H | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV50876437; called by muse, mutect2
- IZUMO1 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55802270; called by muse, mutect2
- KLF10 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV53434759; called by muse, mutect2
- LMNTD1 | c.1165T>C p.*389Qext*10 | Nonstop Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV51444667; called by muse, mutect2
- MAGEA4 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs572691118, COSV52340161; called by muse, mutect2, varscan2
- MAVS | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63926458; called by muse, mutect2, varscan2
- MUC17 | c.3053C>G p.T1018S | Missense Mutation (SNP) | VAF 28/607 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV60279772; called by muse, mutect2
- NLRP5 | c.1178G>C p.S393T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66762001, COSV66764507; called by muse, mutect2, varscan2
- OR4S2 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 37/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56745863, COSV56745901; called by muse, mutect2
- OR7D4 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | catalogued as COSV58071142; called by muse, mutect2
- PCDHB15 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs371639102; called by muse, mutect2
- PHF20 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV59184459; called by muse, mutect2
- PHF3 | c.2990T>A p.F997Y | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as COSV50313173; called by muse, mutect2
- PLCH1 | c.2998G>C p.A1000P (on ENST00000340059 / NM_001130960.2; = p.A992P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV58186255, COSV58200092; called by muse, mutect2
- PLXNC1 | c.3700A>G p.K1234E | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51569309; called by muse, mutect2
- PRNP | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs755417301, COSV65173473; called by muse, mutect2, varscan2
- PSMC2 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53006477; called by muse, mutect2
- RNF133 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57349038; called by muse, mutect2
- RNF157 | c.901T>C p.C301R | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53941843; called by muse, mutect2
- RPGRIP1L | c.1152G>C p.Q384H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50902629; called by muse, mutect2
- SAMD9 | c.2167G>C p.D723H | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs1321968696, COSV66072968; called by muse, mutect2
- SEMA5A | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs773789880, COSV66784511; called by muse, mutect2
- SERPINB11 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV66956407; called by muse, mutect2
- SHOC1 | c.2917A>G p.T973A | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59497547; called by muse, mutect2
- SI | c.3775G>C p.D1259H | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52265800; called by muse, mutect2
- SLAMF6 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63586403, COSV99058396; called by muse, mutect2
- SLC35G3 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52010138; called by muse, mutect2
- SLC4A1AP | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV58133625; called by muse, mutect2
- SLC5A6 | c.1590C>A p.Y530* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | catalogued as COSV60158370; called by muse, mutect2
- SRSF5 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 11/339 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67936380; called by muse, mutect2
- STAM | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV66324871; called by muse, mutect2
- TDRD10 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.948); catalogued as COSV63811243; called by muse, mutect2, varscan2
- THAP12 | c.1598A>C p.E533A | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99473107; called by muse, mutect2
- TMC1 | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 6/174 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs969922326, COSV52767299; called by muse, mutect2
- TOPBP1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV53432250, COSV99605889; called by muse, mutect2
- TRRAP | c.4691G>A p.R1564Q (on ENST00000359863 / NM_001244580.1; = p.R1546Q on NM_003496.3) | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1554417413, COSV62838705; called by muse, mutect2
- TTN | c.15706C>T p.Q5236* (on ENST00000591111; = p.Q4309* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/220 reads (7%) | catalogued as rs1560810766, COSV59884028; called by muse, mutect2
- UBA2 | c.1370A>C p.H457P | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.474); catalogued as COSV55827256; called by muse, mutect2
- UHRF1BP1 | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV51952635; called by muse, mutect2
- WNK3 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63612068; called by muse, mutect2, varscan2
- ZBTB33 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58533120; called by muse, varscan2
- ZFHX4 | c.3166A>G p.T1056A | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV50491340; called by muse, mutect2
- ZNF284 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69690630; called by muse, mutect2
- ZNF311 | c.1436C>A p.A479D | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV65852831; called by muse, mutect2
- ZNF345 | c.1334A>C p.Q445P | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59322649, COSV59324272; called by muse, mutect2
- ZNF667 | c.1350A>C p.K450N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52631100; called by muse, mutect2
- CTTNBP2NL | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SIRPA | c.539T>G p.I180S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SULF2 | c.1563dup p.L522Tfs*34 | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | called by mutect2, pindel, varscan2
- TRAV20 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANKRD53 | c.252C>T p.T84= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV55536351; called by muse, mutect2
- ANKS1B | c.2076C>G p.T692= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV61334732; called by muse, mutect2
- APCDD1 | c.273C>A p.I91= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV62372020; called by muse, mutect2, varscan2
- CHAT | c.1483T>C p.L495= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV60320089; called by muse, mutect2
- EIF4E1B | c.129G>C p.L43= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100024784; called by muse, mutect2
- GJA1 | c.774A>G p.K258= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs758166001, COSV56996928; called by muse, mutect2
- KIAA1586 | c.786T>G p.P262= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100875370; called by muse, mutect2
- MFNG | c.588T>A p.T196= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV63689955; called by muse, mutect2, varscan2
- MID1 | c.9A>G p.T3= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV58191568; called by muse, mutect2, varscan2
- OBSCN | c.2631G>A p.V877= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV52739168; called by muse, varscan2
- OR6C74 | c.855C>A p.P285= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV100667776; called by muse, mutect2
- PLCB2 | c.204C>T p.R68= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV53030730; called by muse, mutect2
- POTEA | c.1107T>C p.D369= (on ENST00000519951 / NM_001005365.2; = p.D323= on NM_001002920.1) | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs1448199376; called by muse, mutect2
- SCN8A | c.2415A>T p.I805= | Silent (SNP) | VAF 24/410 reads (6%) | catalogued as COSV61976455; called by muse, mutect2
- SDK1 | c.1059G>A p.T353= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs371044483; called by muse, mutect2, varscan2
- SEPHS2 | c.630G>C p.V210= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV72100706; called by muse, mutect2, varscan2
- SNCAIP | c.2358T>C p.T786= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV54402143; called by muse, mutect2
- SORCS3 | c.2922C>T p.T974= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs752215487, COSV63793286; called by muse, mutect2, varscan2
- TSLP | c.459A>T p.R153= | Silent (SNP) | VAF 7/189 reads (4%) | catalogued as COSV61291224; called by muse, mutect2
- TULP2 | c.657G>A p.K219= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV55476794; called by muse, mutect2
- UNC5B | c.1284G>C p.T428= | Silent (SNP) | VAF 24/366 reads (7%) | catalogued as COSV58974311; called by muse, mutect2
- ELMO3 | c.1421-35T>G | Intron (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100440902; called by muse, mutect2
